Somatic mutation profile of tumor specimen 0DOTFS from CCDI case PBCCTY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.8 years (1,399 days).
Specimen 0DOTFS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5a020ab-fc60-467e-ac3d-6d80c5ca5ebb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOTFP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14d34618-ef43-4407-951e-06e983260e48

The open-access MAF lists 21 somatic variants for this specimen: 10 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 8, Missense Mutation 7, 5'UTR 2, In Frame Del 2, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.2033dup p.I679Dfs*21 | Frame Shift Ins (INS) | VAF 297/370 reads (80%) | catalogued as rs587781807; ClinVar: pathogenic; called by mutect2, varscan2
- ELF5 | c.706T>C p.Y236H (on ENST00000312319 / NM_198381.2; = p.Y226H on NM_001422.4) | Missense Mutation (SNP) | VAF 151/547 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1390630267; called by muse, mutect2, varscan2
- EPHB2 | c.2098G>A p.E700K (on ENST00000400191 / NM_001309193.2; = p.E701K on NM_004442.7) | Missense Mutation (SNP) | VAF 377/937 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1427054038, COSV65860563; called by muse, mutect2, varscan2
- KCNA10 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 337/794 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755048620, COSV63904386; called by muse, mutect2
- MBD6 | c.151C>T p.R51W | Missense Mutation (SNP) | VAF 215/548 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs1438342608; called by muse, mutect2, varscan2
- OR6F1 | c.739G>A p.V247M | Missense Mutation (SNP) | VAF 296/806 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs369128749; called by muse, mutect2
- DSC3 | c.383C>A p.T128N | Missense Mutation (SNP) | VAF 249/829 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- GABRA6 | c.399T>A p.N133K | Missense Mutation (SNP) | VAF 152/436 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OCA2 | c.199_201del p.E67del | In Frame Del (DEL) | VAF 155/528 reads (29%) | called by mutect2, varscan2
- TP53 | c.461_469del p.G154_R156del | In Frame Del (DEL) | VAF 337/435 reads (77%) | called by mutect2, varscan2
- ABCC9 | c.1401G>T p.A467= | Silent (SNP) | VAF 312/748 reads (42%) | called by muse, mutect2, varscan2
- AGO4 | c.1525C>T p.L509= | Silent (SNP) | VAF 283/633 reads (45%) | called by muse, mutect2, varscan2
- AKAP9 | c.3810C>G p.L1270= | Silent (SNP) | VAF 205/668 reads (31%) | called by muse, mutect2, varscan2
- C1orf68 | c.156T>C p.T52= | Silent (SNP) | VAF 249/578 reads (43%) | catalogued as rs781084630; called by muse, varscan2
- FAM171A1 | c.2143A>C p.R715= | Silent (SNP) | VAF 228/546 reads (42%) | called by muse, mutect2, varscan2
- OR8S1 | c.24C>A p.T8= | Silent (SNP) | VAF 55/371 reads (15%) | called by muse, mutect2, varscan2
- PCDHA3 | c.2055C>T p.G685= | Silent (SNP) | VAF 117/276 reads (42%) | catalogued as rs1554122674; called by muse, mutect2, varscan2
- SPTBN5 | c.2256G>A p.A752= | Silent (SNP) | VAF 111/359 reads (31%) | called by muse, mutect2, varscan2
- AGO3 | c.-58T>A | 5'UTR (SNP) | VAF 133/339 reads (39%) | called by muse, mutect2, varscan2
- GRB14 | c.928-14C>T | Intron (SNP) | VAF 60/243 reads (25%) | called by muse, mutect2, varscan2
- KLK9 | c.-38G>A | 5'UTR (SNP) | VAF 28/317 reads (9%) | catalogued as rs766343476; called by muse, mutect2
